Somatic mutation profile of tumor specimen C3L-09059-01 (aliquot CPT0483030009) from CPTAC case C3L-09059, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.7 years (26,901 days).
Specimen C3L-09059-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f3b38d4-c1ad-43f7-bdd8-89aebd30f7db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09059-31 (Blood Derived Normal), aliquot CPT0483180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af64fae7-84f4-4142-8c41-a66e096737ce

The open-access MAF lists 80 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, Intron 1, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 69/271 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 46/689 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1299828769; called by muse, mutect2
- CACNA1I | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 118/530 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as COSV60805015; called by muse, mutect2, varscan2
- CILK1 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs766439765; called by muse, mutect2, varscan2
- CYLC1 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV61416789; called by muse, mutect2, varscan2
- DISP1 | c.3079C>A p.L1027I | Missense Mutation (SNP) | VAF 23/517 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99451426, COSV99451638; called by muse, mutect2
- FAM189B | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 60/584 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1265544576; called by muse, varscan2
- FBXO15 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs144253482, COSV54044307; called by muse, mutect2
- FHOD1 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759719315; called by muse, mutect2, varscan2
- FLRT2 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1248212249, COSV58136841; called by muse, mutect2, varscan2
- HRH1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs749156342, COSV67956167; called by muse, mutect2, varscan2
- KIF1A | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100241800; called by muse, mutect2, varscan2
- KMT2B | c.2761C>T p.R921W | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs749911178; called by muse, mutect2, varscan2
- LEXM | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs777462327, COSV64022668; called by muse, mutect2, varscan2
- LIPA | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs763989780, COSV100290398, COSV60328854; called by muse, varscan2
- MDM1 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 25/188 reads (13%) | catalogued as COSV57447769; called by mutect2, varscan2
- NAAA | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 38/407 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781494116, COSV54431522; called by muse, mutect2
- OR2T10 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV57896851; called by muse, mutect2, varscan2
- PABPN1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 42/617 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs778129238; called by muse, mutect2
- PPFIA2 | c.3526G>T p.A1176S | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.123); catalogued as rs984025704; called by muse, mutect2, varscan2
- PRAM1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 31/479 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs373788642; called by muse, mutect2
- PRKD2 | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1474936936; called by muse, mutect2
- REG3A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.428); catalogued as rs372756064, COSV100532746, COSV59411342; called by muse, mutect2, varscan2
- TBKBP1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64654129; called by muse, mutect2
- ZFAT | c.2906C>T p.T969M | Missense Mutation (SNP) | VAF 54/731 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs777595729, COSV64739760; called by muse, mutect2
- ZNF710 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 90/601 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.143); catalogued as rs375929851; called by muse, mutect2, varscan2
- ZNF843 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 25/475 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.447); catalogued as rs1193846048; called by muse, mutect2
- AAMP | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- ALS2CL | c.2821C>T p.H941Y | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.276); called by muse, varscan2
- ARHGAP5 | c.753C>G p.S251R | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- C16orf72 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2
- C5orf38 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CBARP | c.566C>G p.T189R (on ENST00000382477; = p.T169R on NM_152769.3) | Missense Mutation (SNP) | VAF 22/507 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH7 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- COL4A3 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCF | c.1306A>G p.K436E | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DNAH11 | c.8067C>A p.F2689L | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECTD4 | c.8581G>A p.A2861T | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KATNA1 | c.1301G>C p.R434T | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSBPL9 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDE3B | c.1601C>A p.P534H | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPL10A | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SHANK1 | c.6242T>G p.L2081R | Missense Mutation (SNP) | VAF 25/574 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SLC1A3 | c.1421del p.F474Sfs*29 | Frame Shift Del (DEL) | VAF 22/239 reads (9%) | called by mutect2, varscan2
- SLC35F4 | c.397G>T p.A133S (on ENST00000339762 / NM_001352015.2; = p.A97S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAPC1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2
- SPTA1 | c.5138A>T p.Y1713F | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.449); called by muse, mutect2
- SPTA1 | c.5137T>A p.Y1713N | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2
- SRRM2 | c.3344G>C p.R1115T | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- STMN3 | c.379_381del p.N127del | In Frame Del (DEL) | VAF 84/445 reads (19%) | called by pindel, varscan2
- TRPC4AP | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WBP11 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- WDR19 | c.3467G>T p.S1156I | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.1306G>C p.G436R (on ENST00000628543; = p.G611R on NM_152381.6) | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XKR4 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.136); called by muse, mutect2
- ADAMTSL1 | c.2769C>T p.H923= | Silent (SNP) | VAF 82/426 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.3768G>C p.L1256= | Silent (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- AXL | c.522C>T p.L174= | Silent (SNP) | VAF 83/449 reads (18%) | called by muse, mutect2, varscan2
- BPIFB4 | c.1641C>A p.T547= | Silent (SNP) | VAF 122/385 reads (32%) | called by muse, mutect2, varscan2
- DYSF | c.1449G>A p.S483= | Silent (SNP) | VAF 55/271 reads (20%) | catalogued as rs755103680, COSV50267426; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- ERN2 | c.1863G>T p.L621= | Silent (SNP) | VAF 42/318 reads (13%) | catalogued as COSV55622118; called by muse, mutect2, varscan2
- FHOD3 | c.3441C>T p.I1147= (on ENST00000359247 / NM_001281739.3; = p.I1164= on NM_025135.5) | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as rs754477560, COSV57165551; called by muse, mutect2, varscan2
- GABRG2 | c.1224C>T p.D408= (on ENST00000361925 / NM_001375343.1; = p.D368= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/324 reads (17%) | called by muse, mutect2, varscan2
- GJA8 | c.714G>A p.R238= | Silent (SNP) | VAF 30/470 reads (6%) | catalogued as rs1457222860; called by muse, mutect2
- H4C12 | c.213G>A p.V71= | Silent (SNP) | VAF 27/257 reads (11%) | catalogued as rs764527111; called by muse, mutect2, varscan2
- MFSD2B | c.1386C>T p.G462= | Silent (SNP) | VAF 48/574 reads (8%) | catalogued as rs766151038, COSV57855221; called by muse, mutect2
- MNDA | c.993C>T p.S331= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs993369232, COSV63740362; called by muse, mutect2
- OMA1 | c.1371C>G p.L457= | Silent (SNP) | VAF 15/167 reads (9%) | called by muse, mutect2
- OR2L5 | c.618T>G p.L206= | Silent (SNP) | VAF 63/310 reads (20%) | called by muse, mutect2, varscan2
- PRMT5 | c.15G>C p.A5= | Silent (SNP) | VAF 58/393 reads (15%) | catalogued as rs775577695, COSV53545555; called by muse, mutect2, varscan2
- RAB3IL1 | c.180C>T p.D60= | Silent (SNP) | VAF 79/536 reads (15%) | catalogued as COSV100076533; called by muse, mutect2, varscan2
- RPS6KL1 | c.1014C>T p.D338= | Silent (SNP) | VAF 39/621 reads (6%) | catalogued as rs777862799; called by muse, mutect2
- SCN9A | c.5640C>A p.I1880= (on ENST00000303354; = p.I1869= on NM_002977.3) | Silent (SNP) | VAF 37/339 reads (11%) | catalogued as COSV100312493; called by muse, mutect2, varscan2
- SHOX2 | c.174G>A p.A58= | Silent (SNP) | VAF 116/797 reads (15%) | catalogued as rs140028034; called by muse, mutect2, varscan2
- SRP72 | c.132C>T p.D44= | Silent (SNP) | VAF 18/277 reads (6%) | catalogued as rs530644774, COSV100714375, COSV61379184; called by muse, mutect2
- ZBTB7C | c.198C>T p.G66= | Silent (SNP) | VAF 25/419 reads (6%) | called by muse, mutect2
- NTAQ1 | c.508+842A>G | Intron (SNP) | VAF 29/373 reads (8%) | called by muse, mutect2
- PKD1L2 | n.206C>T | RNA (SNP) | VAF 41/363 reads (11%) | called by muse, mutect2, varscan2
- PKHD1 | c.*2387G>T | 3'UTR (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- RN7SL495P | chr15:22612257 T>A | 5'Flank (SNP) | VAF 16/318 reads (5%) | called by muse, mutect2
